Somatic mutation profile of tumor specimen 0DPAOI from CCDI case PBCDBS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,297 days).
Specimen 0DPAOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c0b7432-9ca9-477a-9012-07990da25950.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPAO7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f2cd0df-cedd-4bc2-bc52-704acc137d25

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 2, Nonsense Mutation 2, 5'UTR 2, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 288/604 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.4732C>T p.R1578C | Missense Mutation (SNP) | VAF 176/469 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs201529124, CM1110218; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AOAH | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 34/439 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs960341212, COSV51752746; called by muse, mutect2
- ARHGEF33 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 207/442 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV67257255; called by muse, mutect2, varscan2
- CREBBP | c.5040_5042del p.L1681del | In Frame Del (DEL) | VAF 182/367 reads (50%) | catalogued as COSV52125862; called by mutect2, pindel, varscan2
- EEA1 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 162/357 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59288598; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 188/395 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OBSL1 | c.2101G>A p.G701S | Missense Mutation (SNP) | VAF 81/971 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs200180548, COSV54724424; ClinVar: uncertain significance; called by muse, mutect2
- PGGT1B | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 29/634 reads (5%) | catalogued as rs1485841029, COSV56972961; called by muse, mutect2
- PSMA1 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 200/410 reads (49%) | catalogued as COSV67165863; called by muse, mutect2, varscan2
- PTCH2 | c.2662G>A p.D888N | Missense Mutation (SNP) | VAF 268/568 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs745445438, COSV64710466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A46 | c.793A>T p.I265F | Missense Mutation (SNP) | VAF 314/652 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs754848420; called by muse, mutect2, varscan2
- STOX1 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 59/500 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); catalogued as rs754346473, COSV53817299; called by muse, mutect2, varscan2
- TET1 | c.5166G>T p.K1722N | Missense Mutation (SNP) | VAF 91/815 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV65384507, COSV65388494; called by muse, mutect2, varscan2
- ITGA8 | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 88/550 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- RNASEH2B | c.916G>A p.G306S (on ENST00000646960; = p.M248I on NM_001142279.2) | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC47A1 | c.1615A>G p.R539G | Missense Mutation (SNP) | VAF 90/412 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC2 | c.669C>T p.V223= | Silent (SNP) | VAF 82/672 reads (12%) | catalogued as rs753822329; called by muse, mutect2, varscan2
- CYP3A4 | c.-99C>T | 5'UTR (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2
- GPR161 | c.1204+97C>T | Intron (SNP) | VAF 11/85 reads (13%) | catalogued as rs558594115; called by muse, mutect2
- RNH1 | c.272+74G>A | Intron (SNP) | VAF 184/358 reads (51%) | catalogued as rs542149752; called by muse, mutect2, varscan2
- SLC12A4 | c.-57G>A | 5'UTR (SNP) | VAF 268/287 reads (93%) | called by muse, mutect2, varscan2
